Gene-level copy-number profile of specimen HCM-SANG-1088-C18-85A-01D-A80T-32 from HCMI case HCM-SANG-1088-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G1.
Specimen HCM-SANG-1088-C18-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e564c0aa-292e-4d3a-aad1-4e5186c6325d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1088-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,734 have no estimate.
https://portal.gdc.cancer.gov/files/579298ab-5eee-44ea-b5f5-bd444a07541b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 1,640; copy number 2: 15,199; copy number 3: 31,640; copy number 4: 2,558; copy number 5: 4,268; copy number 6: 1,503; copy number 7: 761; copy number 8: 1,315; copy number 9: 3.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,190,901–7,200,857, 2 genes: RPS3AP33, AF228730.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,079 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:76,162,119–129,683,770, 748 genes, copy number 7 (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,328 genes, copy number 7–8 (broad region; genes not listed).
- chr21:8,603,547–8,701,562, 3 genes, copy number 9: RPSAP68, CR381572.2, CR381572.1.

Autosomal genes at a single copy (total copy number 1): 1,088. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
